Somatic mutation profile of tumor specimen 0DWODW from CCDI case PBCPKV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.2 years (2,978 days).
Specimen 0DWODW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6de1770e-0aeb-45ba-80ea-dbbdd45bb147.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWODO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fed45cc9-b7c4-4bb2-a6b8-4de995f9d3c0

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MATN2 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 76/459 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773740212, COSV54719509; called by muse, mutect2, varscan2
- RO60 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 86/583 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as COSV100814299; called by muse, mutect2, varscan2
- SYNE1 | c.9524T>C p.M3175T (on ENST00000367255 / NM_182961.4; = p.M3182T on NM_033071.3) | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1239643434; called by muse, mutect2, varscan2
- ARV1 | c.431T>C p.F144S | Missense Mutation (SNP) | VAF 72/409 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFT80 | c.1775T>G p.L592R | Missense Mutation (SNP) | VAF 84/506 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- ITPKB | c.2244C>A p.I748= | Splice Region (SNP) | VAF 80/547 reads (15%) | called by muse, mutect2, varscan2
- SNCAIP | c.2509G>A p.D837N | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- CEP120 | c.1611G>A p.K537= | Silent (SNP) | VAF 43/219 reads (20%) | catalogued as rs761014693; called by muse, mutect2, varscan2
- RC3H1 | c.3363C>T p.D1121= | Silent (SNP) | VAF 50/391 reads (13%) | called by muse, mutect2, varscan2
- SCAF4 | c.912T>C p.A304= | Silent (SNP) | VAF 97/549 reads (18%) | called by muse, mutect2, varscan2
- GALR2 | c.*19C>T | 3'UTR (SNP) | VAF 66/344 reads (19%) | catalogued as rs1247995244; called by muse, mutect2, varscan2
